Somatic mutation profile of tumor specimen TCGA-85-A4CL-01A (aliquot TCGA-85-A4CL-01A-41D-A26M-08) from TCGA case TCGA-85-A4CL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.7 years (24,005 days).
Specimen TCGA-85-A4CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b58648dd-c98b-401a-882f-6d2fe2855a1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A4CL-10A (Blood Derived Normal), aliquot TCGA-85-A4CL-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f608efbe-51d9-43ff-9bd5-2b7f743c5bd8

The open-access MAF lists 872 somatic variants for this specimen: 625 protein-altering or splice-affecting, 221 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 556, Silent 221, Nonsense Mutation 40, Frame Shift Del 10, Splice Site 8, Intron 8, RNA 8, Splice Region 5, Frame Shift Ins 4, 5'UTR 4, 5'Flank 3, Nonstop Mutation 2.

Variants (750 of 872; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1679G>A p.R560Q (on ENST00000359125 / NM_172107.4; = p.R532Q on NM_004518.6) | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517919, COSV60556829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs786201066, CM125324, COSV51875886, COSV99254695; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- TP53 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2
- ABL1 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV100584771; called by muse, mutect2, varscan2
- AC013489.1 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.042); catalogued as rs775160112, COSV51551420, COSV99183909; called by muse, mutect2, varscan2
- ACSM1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as rs151107402; called by muse, varscan2
- ACTN2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100857092; called by muse, mutect2, varscan2
- ADA2 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99376556; called by muse, mutect2, varscan2
- ADAM15 | c.2365G>A p.D789N (on ENST00000356955 / NM_207197.3; = p.D764N on NM_207195.3) | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1364887313, COSV99665429; called by muse, mutect2, varscan2
- ADAM19 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57438295; called by muse, mutect2, varscan2
- ADAM22 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55970780, COSV99718649; called by muse, mutect2, varscan2
- ADAMTS18 | c.1898G>C p.R633P | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99273542, COSV99274550; called by muse, mutect2, varscan2
- ADAMTS20 | c.2995C>A p.H999N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV101166147, COSV67128635; called by muse, mutect2, varscan2
- ADAMTSL3 | c.764G>C p.R255P | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99721647; called by muse, mutect2, varscan2
- ADCY10 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100897137; called by muse, mutect2, varscan2
- AFDN | c.2461C>T p.Q821* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100653711; called by muse, mutect2, varscan2
- AFF4 | c.3232G>T p.A1078S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV54794541; called by muse, mutect2, varscan2
- AFG3L2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV99302247; called by muse, mutect2, varscan2
- AGRN | c.5894C>T p.S1965F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as rs893046448, COSV101039156; called by muse, varscan2
- AHNAK | c.3945G>C p.E1315D | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57206484, COSV99950093; called by muse, mutect2, varscan2
- AKT3 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); catalogued as COSV55639370; called by muse, mutect2, varscan2
- AKT3 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV55612517; called by muse, mutect2, varscan2
- ALDH8A1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99665073; called by muse, mutect2, varscan2
- ALMS1 | c.6463G>C p.D2155H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100044036, COSV52522633; called by muse, mutect2, varscan2
- ALMS1 | c.6742G>A p.E2248K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100044037; called by muse, mutect2, varscan2
- ALPK2 | c.5374dup p.I1792Nfs*4 | Frame Shift Ins (INS) | VAF 13/47 reads (28%) | catalogued as rs773899571; called by mutect2, varscan2
- ALPK2 | c.4780G>A p.E1594K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.484); catalogued as COSV100864915; called by muse, mutect2, varscan2
- AMOTL2 | c.2057C>G p.S686C | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); catalogued as COSV99850747; called by muse, mutect2
- ANK3 | c.7681G>A p.E2561K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as COSV99782862; called by muse, mutect2, varscan2
- ANKRD17 | c.5462C>T p.S1821L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV100430104; called by muse, mutect2, varscan2
- ANKRD44 | c.828G>C p.L276F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99986182; called by muse, mutect2, varscan2
- ANOS1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99391594; called by muse, mutect2, varscan2
- APC2 | c.5055G>C p.E1685D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as COSV99279967; called by muse, mutect2, varscan2
- APLP1 | c.1703G>A p.R568K (on ENST00000221891 / NM_001024807.3; = p.R567K on NM_005166.4) | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.957); catalogued as COSV99697996; called by muse, mutect2, varscan2
- ARFGEF2 | c.4180-1G>A p.X1394_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100904537; called by muse, mutect2, varscan2
- ARHGAP24 | c.1765G>A p.E589K (on ENST00000395184 / NM_001025616.3; = p.E496K on NM_031305.3) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV99982311; called by muse, mutect2, varscan2
- ARHGAP32 | c.1642G>A p.E548K (on ENST00000310343 / NM_001378025.1; = p.E199K on NM_014715.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100089654; called by muse, mutect2, varscan2
- ARHGEF11 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV100810443; called by muse, mutect2, varscan2
- ARHGEF11 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100810444; called by muse, mutect2, varscan2
- ARHGEF12 | c.1298C>G p.S433* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100755273; called by muse, mutect2
- ARHGEF12 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs1318160785, COSV100755274, COSV63102985; called by muse, mutect2
- ARHGEF26 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs368674648, COSV62844927; called by muse, mutect2, varscan2
- ARID1B | c.4855+1G>T p.X1619_splice | Splice Site (SNP) | VAF 34/102 reads (33%) | catalogued as COSV99272987; called by muse, mutect2, varscan2
- ARMC4 | c.2623A>G p.M875V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100537496; called by muse, mutect2
- ARRB2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99347330; called by muse, mutect2, varscan2
- ASAP1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100728028; called by muse, mutect2, varscan2
- ATP1A3 | c.331G>A p.A111T (on ENST00000545399 / NM_001256214.2; = p.A98T on NM_152296.5) | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100132614; called by muse, mutect2, varscan2
- ATP2A1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100837474; called by muse, mutect2, varscan2
- ATR | c.4093G>T p.D1365Y | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100638685; called by muse, mutect2, varscan2
- AVEN | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV100145935, COSV60736682; called by muse, mutect2, varscan2
- BAP1 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56234168, COSV99964597; called by muse, mutect2, varscan2
- BCL9 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99326011; called by muse, mutect2, varscan2
- BCO1 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV50732604, COSV99258810; called by muse, mutect2, varscan2
- BIRC5 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV100051512; called by muse, mutect2, varscan2
- BMP2K | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1240599340, COSV99785523; called by muse, mutect2, varscan2
- BNIP2 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs1281499052, COSV99985927; called by muse, mutect2, varscan2
- BRDT | c.2164C>G p.H722D | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV100746620; called by muse, mutect2, varscan2
- BRWD3 | c.746G>A p.W249* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100956640; called by muse, mutect2, varscan2
- BTAF1 | c.1839G>C p.L613F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56437593, COSV99795927; called by muse, mutect2, varscan2
- BUB1 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.314); catalogued as COSV100241734; called by muse, mutect2, varscan2
- C18orf54 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV100266739; called by muse, mutect2, varscan2
- C1orf87 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV100967285; called by muse, mutect2, varscan2
- CABIN1 | c.2705G>A p.R902K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99574204; called by muse, mutect2, varscan2
- CACNA2D3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55537526; called by muse, mutect2, varscan2
- CADM3 | c.1157G>T p.G386V (on ENST00000368125 / NM_001127173.3; = p.G420V on NM_021189.5) | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100929694; called by muse, mutect2, varscan2
- CAND2 | c.1008G>C p.E336D (on ENST00000456430 / NM_001162499.2; = p.E243D on NM_012298.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99929967; called by muse, mutect2, varscan2
- CBWD5 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV101070746; called by muse, mutect2, varscan2
- CCDC170 | c.1779G>A p.M593I | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV99498981; called by muse, mutect2, varscan2
- CCDC78 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV99285241; called by muse, mutect2, varscan2
- CCIN | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.846); catalogued as COSV100631966; called by muse, mutect2, varscan2
- CCN6 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.519); catalogued as COSV100037239; called by muse, mutect2, varscan2
- CCNDBP1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs767075145, COSV99543928; called by muse, mutect2, varscan2
- CCNT1 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs1390840609, COSV99980943; called by muse, mutect2, varscan2
- CCSER2 | c.1932C>G p.F644L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV99826639; called by muse, mutect2, varscan2
- CD36 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs766961875, COSV99988036; called by muse, mutect2, varscan2
- CDC42BPA | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV100507090; called by muse, mutect2, varscan2
- CDC73 | c.1220G>T p.R407I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100814054; called by muse, mutect2, varscan2
- CDH13 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99227344, COSV99232011; called by muse, mutect2, varscan2
- CDH9 | c.2116C>A p.L706M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV50343071, COSV99141911; called by muse, mutect2, varscan2
- CEP126 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV99681546; called by muse, mutect2
- CEP290 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV100470130; called by muse, mutect2, varscan2
- CEP350 | c.8841C>G p.I2947M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV100855398; called by muse, mutect2, varscan2
- CEP63 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1299046331, COSV100133166; called by muse, mutect2, varscan2
- CFAP221 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs1305191928, COSV99733290; called by muse, mutect2
- CFH | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100661687; called by muse, mutect2, varscan2
- CFLAR | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.01); catalogued as COSV100010001; called by muse, mutect2, varscan2
- CHD1 | c.4558C>T p.H1520Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99400022; called by muse, mutect2
- CHD1L | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs1231736748, COSV100787664; called by muse, mutect2, varscan2
- CHSY1 | c.1826C>G p.S609* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99574302; called by muse, mutect2, varscan2
- CHUK | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100957297; called by muse, mutect2, varscan2
- CIART | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV99290455; called by muse, mutect2
- CKAP5 | c.5455C>G p.R1819G (on ENST00000529230 / NM_001008938.4; = p.R1759G on NM_014756.3) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.394); catalogued as rs773861293, COSV100371578; called by muse, mutect2, varscan2
- CLEC4D | c.264G>C p.W88C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100223212; called by muse, mutect2, varscan2
- CLPB | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs377401155, COSV99578701, COSV99578840; called by muse, mutect2
- CLVS2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as COSV99253706; called by muse, mutect2, varscan2
- CLYBL | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100185807; called by muse, mutect2
- CMSS1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV101375666; called by muse, mutect2, varscan2
- CNTN1 | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs773622747, COSV100751996; called by muse, mutect2, varscan2
- COG1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100245233, COSV100245477; called by muse, mutect2, varscan2
- COL15A1 | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100898062; called by muse, mutect2, varscan2
- COL4A5 | c.3695G>T p.G1232V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100090432; called by muse, mutect2, varscan2
- COL6A3 | c.1441C>G p.L481V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.192); catalogued as COSV99802222; called by muse, mutect2, varscan2
- CPA4 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs3735053, COSV55982848; called by muse, mutect2, varscan2
- CPEB2 | c.1686G>A p.W562* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99470771; called by muse, mutect2, varscan2
- CPNE8 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58843440; called by muse, mutect2
- CPS1 | c.3541G>A p.V1181I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs759207426, COSV99244369; called by muse, mutect2, varscan2
- CSMD1 | c.3194del p.G1065Efs*4 (on ENST00000520002; = p.G1064Efs*4 on NM_033225.6) | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as COSV59403299; called by mutect2, pindel, varscan2
- CSMD3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.856); catalogued as COSV52105591, COSV52111082; called by muse, mutect2, varscan2
- CSNK2A1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV99424775; called by muse, mutect2
- CST8 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1802329, COSV99850118; called by muse, mutect2, varscan2
- CTNNA3 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV101041700; called by muse, mutect2, varscan2
- CTTNBP2 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99355068; called by muse, mutect2, varscan2
- CUBN | c.9084C>G p.F3028L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV64725365; called by muse, mutect2, varscan2
- CUEDC1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100804826; called by muse, mutect2, varscan2
- CUX2 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as COSV99920996; called by muse, mutect2, varscan2
- CXXC5 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs375744665; called by muse, varscan2
- CYBB | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101059837; called by muse, mutect2, varscan2
- DBN1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV52787402, COSV99446709; called by muse, mutect2, varscan2
- DCC | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100500484, COSV100502334, COSV100503566; called by muse, mutect2, varscan2
- DCST1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as rs1200793653, COSV99665427; called by muse, mutect2, varscan2
- DDIAS | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs1195009673, COSV100231498; called by muse, mutect2, varscan2
- DEFB132 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101212639; called by muse, mutect2, varscan2
- DEPDC1B | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99409964; called by muse, mutect2, varscan2
- DKKL1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.165); catalogued as rs748501492, COSV99678836; called by muse, mutect2, varscan2
- DMRTC2 | c.1104G>C p.*368Yext*14 | Nonstop Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as rs782640790, COSV54187167; called by muse, mutect2, varscan2
- DNAAF1 | c.573C>G p.L191= | Splice Region (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100533851, COSV57579248; called by muse, mutect2
- DNAH11 | c.6730G>C p.E2244Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100181326; called by muse, mutect2, varscan2
- DNAH7 | c.10934G>A p.R3645K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418093; called by muse, mutect2, varscan2
- DNAH7 | c.1971C>G p.F657L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV100418094; called by muse, mutect2, varscan2
- DNAH9 | c.12412G>A p.E4138K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99308701; called by muse, mutect2, varscan2
- DNAJC13 | c.5929G>A p.E1977K | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99608306; called by muse, mutect2, varscan2
- DNAJC2 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.931); catalogued as rs189317813, COSV99972021; called by muse, mutect2, varscan2
- DNM3 | c.137C>G p.S46W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100798281, COSV100798765; called by muse, mutect2, varscan2
- DNTT | c.990G>A p.M330I | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100960796; called by muse, mutect2, varscan2
- DOCK2 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56942553; called by muse, mutect2, varscan2
- DOCK2 | c.5463G>T p.Q1821H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.085); catalogued as COSV56959181, COSV56994668; called by muse, mutect2, varscan2
- DOCK3 | c.2419G>C p.E807Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99815759; called by muse, mutect2, varscan2
- DPPA4 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV59512669; called by muse, mutect2, varscan2
- DRAM1 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99315887; called by muse, mutect2, varscan2
- DSC2 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99199584, COSV99199927; called by muse, mutect2, varscan2
- DSP | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV65792423; called by muse, mutect2, varscan2
- DSPP | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV56815492; called by muse, mutect2, varscan2
- ECPAS | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99399494; called by muse, mutect2, varscan2
- EEF1G | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100240711; called by muse, varscan2
- EFL1 | c.2414G>C p.G805A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99189108; called by muse, mutect2
- EGFLAM | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100380679, COSV100380903; called by muse, mutect2, varscan2
- EIF1 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100179557, COSV60422872; called by muse, mutect2
- EIF2AK3 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV100304213; called by muse, mutect2, varscan2
- EIF3K | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.199); catalogued as COSV99943227; called by muse, mutect2, varscan2
- EMC2 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs760435179, COSV55209227, COSV99624640; called by muse, mutect2
- EMILIN3 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100182864; called by muse, mutect2, varscan2
- EML4 | c.926C>G p.T309R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100581496; called by muse, mutect2, varscan2
- ENC1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as rs775163977, COSV56630984; called by muse, mutect2, varscan2
- ENOX1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54892643, COSV99817511; called by muse, mutect2, varscan2
- ENTPD1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as COSV100967846; called by muse, mutect2, varscan2
- ENTPD7 | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100978508; called by muse, mutect2, varscan2
- EP300 | c.4525T>C p.W1509R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607220, COSV99610081; called by muse, mutect2, varscan2
- EP400 | c.4465C>G p.Q1489E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.448); catalogued as COSV100202523; called by muse, mutect2, varscan2
- EPHA5 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV56671369, COSV56679842; called by muse, mutect2, varscan2
- ERCC6 | c.3115A>G p.R1039G | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100876324; called by muse, mutect2, varscan2
- EYS | c.1676C>A p.A559D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV60977829; called by muse, mutect2, varscan2
- F13A1 | c.894C>A p.D298E | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV99344199; called by muse, mutect2, varscan2
- FAM135A | c.4466G>A p.R1489K (on ENST00000370479 / NM_001351599.1; = p.R1276K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99526792; called by muse, mutect2, varscan2
- FAM155A | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV101030837; called by muse, mutect2, varscan2
- FAM98A | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53211479, COSV99479599; called by muse, mutect2, varscan2
- FANCI | c.3919G>C p.E1307Q (on ENST00000310775 / NM_001376911.1; = p.E1247Q on NM_018193.3) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99175128; called by muse, mutect2
- FANCL | c.96+2T>A p.X32_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99288051; called by muse, mutect2, varscan2
- FBN3 | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562018; called by muse, mutect2, varscan2
- FBXO41 | c.918G>C p.Q306H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV99721677; called by muse, mutect2, varscan2
- FEM1B | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100183775; called by muse, mutect2, varscan2
- FGD1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs758037401, COSV64308048, COSV64309225; called by muse, mutect2, varscan2
- FGG | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100272127; called by muse, mutect2, varscan2
- FLG | c.10657G>C p.E3553Q | Missense Mutation (SNP) | VAF 103/452 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.298); catalogued as COSV64243647; called by muse, mutect2, varscan2
- FLT1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV99169404; called by muse, mutect2, varscan2
- FMN2 | c.4870C>G p.Q1624E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.765); catalogued as COSV100147621; called by muse, mutect2, varscan2
- FMO1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV100707990; called by muse, mutect2, varscan2
- FN1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1326993663, COSV100118502; called by muse, mutect2, varscan2
- FNBP1 | c.1596G>C p.M532I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100852842; called by muse, mutect2, varscan2
- FRAS1 | c.8293G>A p.E2765K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs778794208, COSV99356448; called by muse, mutect2, varscan2
- FRMD4A | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99198711; called by muse, mutect2, varscan2
- FRMPD4 | c.3741G>C p.L1247F | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.11); catalogued as COSV101044280; called by muse, mutect2, varscan2
- GABPB2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as rs772956915, COSV100927324; called by muse, mutect2, varscan2
- GABRB2 | c.78-1G>C p.X26_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99196871; called by muse, mutect2, varscan2
- GABRR3 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV101512259, COSV101512365; called by muse, mutect2, varscan2
- GALNT10 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770061; called by muse, mutect2, varscan2
- GALNT10 | c.1693G>C p.D565H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99770064; called by muse, mutect2
- GALNT18 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99926123; called by muse, mutect2, varscan2
- GAS2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs1205756000, COSV99535117; called by muse, mutect2, varscan2
- GBP3 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99352794; called by muse, mutect2, varscan2
- GCNT4 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV100466656; called by muse, mutect2, varscan2
- GEMIN5 | c.4004C>G p.P1335R | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV99594409; called by muse, mutect2
- GEN1 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs757163395, COSV100438025; called by muse, mutect2, varscan2
- GJA1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs868186719, COSV99247381; called by muse, mutect2, varscan2
- GLUD1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.203); catalogued as COSV99518470; called by muse, mutect2, varscan2
- GON4L | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99676068; called by muse, mutect2, varscan2
- GPATCH1 | c.2694G>C p.E898D | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV99404411; called by muse, mutect2
- GPATCH8 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as COSV100132925; called by muse, mutect2
- GPC6 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV100990182; called by muse, mutect2, varscan2
- GPR101 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV99981722; called by muse, varscan2
- GPRC6A | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100114875; called by muse, mutect2, varscan2
- GRIN3B | c.2631G>A p.Q877= | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99313018; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2822G>T p.W941L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.91); catalogued as COSV100441309; called by muse, mutect2
- GTF2IRD2B | c.2823G>T p.W941C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100441312; called by muse, mutect2, varscan2
- H2BC21 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100480223; called by muse, mutect2, varscan2
- H2BC4 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58414879, COSV58417027; called by muse, mutect2
- HADHA | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as rs935397648, COSV101024114, COSV101024258; called by muse, mutect2, varscan2
- HCN1 | c.774G>T p.R258S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100302738, COSV57519790; called by muse, mutect2, varscan2
- HECW1 | c.3481G>C p.E1161Q | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV101224393, COSV67832911; called by muse, mutect2, varscan2
- HELB | c.2366C>G p.S789* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99922277; called by muse, mutect2, varscan2
- HERC2 | c.3058G>T p.A1020S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.956); catalogued as rs778601927, COSV99877449; called by muse, mutect2, varscan2
- HERC5 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52043965, COSV99987283; called by muse, mutect2, varscan2
- HEXB | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV99714774; called by muse, mutect2, varscan2
- HINFP | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV100640897; called by muse, mutect2, varscan2
- HIRA | c.3022C>G p.Q1008E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99600993; called by muse, mutect2, varscan2
- HLA-B | c.749A>G p.Q250R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101318292, COSV69522623; called by muse, mutect2, varscan2
- HNMT | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99698619; called by muse, mutect2, varscan2
- HNRNPF | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV61562164; called by muse, mutect2, varscan2
- HNRNPU | c.1877G>T p.R626I (on ENST00000283179; = p.R688I on NM_004501.3) | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.736); catalogued as COSV51690552, COSV99310783; called by muse, mutect2, varscan2
- HNRNPU | c.1696G>C p.E566Q (on ENST00000283179; = p.E628Q on NM_004501.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV51692300, COSV99310785; called by muse, mutect2, varscan2
- HOOK1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100969282; called by muse, mutect2, varscan2
- HOXC12 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); catalogued as COSV99678846; called by muse, mutect2
- HPX | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV99793590; called by muse, mutect2, varscan2
- HSPA14 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV101000708; called by muse, mutect2
- HUWE1 | c.8254G>C p.D2752H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99474745; called by muse, mutect2, varscan2
- IFIH1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99718956; called by muse, mutect2, varscan2
- IFIT3 | c.1457C>G p.S486* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99261106; called by muse, mutect2, varscan2
- IFT122 | c.2887G>A p.E963K (on ENST00000348417 / NM_052989.3; = p.E904K on NM_018262.4) | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as COSV99959992; called by muse, mutect2
- IFT172 | c.3649C>T p.Q1217* | Nonsense Mutation (SNP) | VAF 22/173 reads (13%) | catalogued as COSV99563548; called by muse, mutect2, varscan2
- IFT172 | c.3433C>T p.H1145Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99563577; called by muse, mutect2
- IFT74 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as COSV101197222; called by muse, mutect2, varscan2
- IGBP1P2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs778700738; called by muse, mutect2, varscan2
- IGSF10 | c.3767C>T p.S1256L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56781478; called by muse, mutect2, varscan2
- IKZF1 | c.38C>G p.S13* | Nonsense Mutation (SNP) | VAF 44/154 reads (29%) | catalogued as COSV100498846; called by muse, mutect2, varscan2
- IL20RA | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100360264; called by muse, mutect2, varscan2
- INCA1 | c.194T>A p.M65K | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100742073; called by muse, mutect2, varscan2
- INPP5K | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); catalogued as COSV100233961; called by muse, mutect2
- INTU | c.1575G>C p.L525F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58873526, COSV58875769; called by muse, mutect2, varscan2
- IQCG | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775824967, COSV99502806; called by muse, mutect2, varscan2
- IQCH | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100246424; called by muse, mutect2, varscan2
- IRAG1 | c.1621T>A p.S541T | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101351834; called by muse, mutect2, varscan2
- IRX3 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as COSV100315444, COSV61668197; called by muse, mutect2, varscan2
- ITGA10 | c.2707C>G p.L903V | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as COSV100995071; called by muse, mutect2, varscan2
- ITGBL1 | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV101098777; called by muse, mutect2, varscan2
- JADE1 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV99886412; called by muse, mutect2, varscan2
- KALRN | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99567765; called by muse, mutect2, varscan2
- KANK3 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.396); catalogued as COSV100445237; called by muse, mutect2, varscan2
- KAT6B | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs1262044689, COSV54752395, COSV99769272; called by muse, mutect2, varscan2
- KCND2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100479148, COSV58570890; called by muse, mutect2, varscan2
- KCNG1 | c.700G>C p.V234L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV100857198; called by muse, mutect2, varscan2
- KCNH8 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.104); catalogued as COSV100111187, COSV60462549; called by muse, mutect2, varscan2
- KCNJ16 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99033415; called by muse, mutect2, varscan2
- KCNJ8 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.592); catalogued as COSV53716291; called by muse, mutect2, varscan2
- KCNK17 | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100950325; called by muse, mutect2, varscan2
- KCNK6 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 10/218 reads (5%) | catalogued as COSV99649516; called by muse, mutect2
- KDM1B | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99924793; called by muse, mutect2, varscan2
- KDM7A | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50096072; called by muse, mutect2, varscan2
- KIAA1109 | c.11140G>A p.E3714K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99190637; called by muse, mutect2, varscan2
- KIDINS220 | c.2524G>T p.V842L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99876606; called by muse, mutect2, varscan2
- KIF16B | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as rs752204724, COSV100735002; called by muse, mutect2, varscan2
- KIF18B | c.1705G>C p.E569Q (on ENST00000593135 / NM_001265577.2; = p.E581Q on NM_001264573.2) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.544); catalogued as COSV100192679; called by muse, mutect2, varscan2
- KIF20B | c.3550G>A p.E1184K (on ENST00000371728 / NM_001284259.2; = p.E1144K on NM_016195.4) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99590871; called by muse, mutect2, varscan2
- KIF4A | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99516432; called by muse, mutect2
- KIF4B | c.862T>A p.Y288N | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101469424; called by muse, mutect2, varscan2
- KIF5A | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV54051921; called by muse, mutect2, varscan2
- KLC3 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101228790, COSV67269878; called by muse, mutect2, varscan2
- KLF5 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs758109296, COSV100890594, COSV66615042; called by muse, mutect2, varscan2
- KLHL4 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100910248; called by muse, mutect2, varscan2
- KLHL6 | c.1865G>C p.*622Sext*42 | Nonstop Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as COSV100385113; called by muse, mutect2, varscan2
- KPNA6 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV101012645; called by muse, mutect2, varscan2
- KPNB1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV99268455; called by muse, mutect2, varscan2
- KRT23 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.752); catalogued as COSV99266076, COSV99266385; called by muse, mutect2, varscan2
- KRT26 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100156635; called by muse, mutect2, varscan2
- KRT27 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV100053405; called by muse, mutect2
- KRTAP5-10 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.111); catalogued as COSV100924172, COSV64795388; called by muse, varscan2
- KRTAP5-7 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as COSV101273251; called by muse, mutect2, varscan2
- LARP4B | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); catalogued as COSV100295770; called by muse, mutect2, varscan2
- LBX2 | c.505G>A p.E169K (on ENST00000377566 / NM_001282430.2; = p.E165K on NM_001009812.2) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52034868; called by muse, mutect2, varscan2
- LCT | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1287547378, COSV51553815; called by muse, mutect2, varscan2
- LGALS3BP | c.1297C>G p.Q433E | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53164674; called by muse, mutect2
- LGSN | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.211); catalogued as COSV101040769; called by muse, mutect2, varscan2
- LIMD2 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV99368752; called by muse, mutect2, varscan2
- LMAN2L | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1292738069, COSV99383694; called by muse, mutect2, varscan2
- LNX1 | c.1580C>T p.S527L (on ENST00000263925 / NM_001126328.3; = p.S431L on NM_032622.2) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV99820730; called by muse, mutect2, varscan2
- LRP1 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99677669; called by muse, mutect2, varscan2
- LRRC37A2 | c.3884C>G p.S1295C | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV100238910; called by muse, mutect2, varscan2
- LRRC7 | c.1603G>T p.A535S (on ENST00000651989 / NM_001370785.2; = p.A502S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.057); catalogued as COSV99230390; called by muse, mutect2, varscan2
- LRRK2 | c.2246G>A p.C749Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs200867751, COSV100111375; called by muse, varscan2
- LRRK2 | c.5106G>T p.M1702I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV100111376; called by muse, mutect2, varscan2
- LSR | c.1723C>T p.R575W (on ENST00000361790; = p.R556W on NM_015925.6) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV55888355, COSV99723411; called by muse, mutect2, varscan2
- LYPD3 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.309); catalogued as COSV99747273; called by muse, mutect2, varscan2
- LYRM1 | c.160-1G>C p.X54_splice | Splice Site (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99534046; called by muse, mutect2, varscan2
- LYST | c.10784G>A p.R3595K | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV101090454; called by muse, mutect2, varscan2
- MAF | c.46C>G p.P16A | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100392019; called by muse, mutect2, varscan2
- MAGEC2 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.286); catalogued as COSV99910015; called by muse, mutect2, varscan2
- MAGEH1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100746850; called by muse, mutect2, varscan2
- MAGEL2 | c.3169G>C p.E1057Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.283); catalogued as COSV100046281; called by muse, mutect2, varscan2
- MAP3K10 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747284453, COSV99454949; called by muse, mutect2, varscan2
- MAP3K15 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100135984; called by muse, mutect2, varscan2
- MAPK10 | c.543G>A p.M181I (on ENST00000359221 / NM_001351625.2; = p.M219I on NM_002753.5) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as rs866249326, COSV100175607; called by muse, mutect2, varscan2
- MAPK8 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827582; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBOAT1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV100209323; called by muse, mutect2, varscan2
- MCFD2 | c.295C>G p.H99D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100109207; called by muse, mutect2, varscan2
- MED13L | c.3134G>T p.R1045L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV56125652, COSV99928908, COSV99930442; called by muse, mutect2, varscan2
- MED16 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs751236372, COSV99515089; called by muse, mutect2, varscan2
- MEI1 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs530444486, COSV100300478; called by muse, mutect2, varscan2
- MIA3 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV100719571; called by muse, mutect2, varscan2
- MIA3 | c.5378G>A p.G1793E | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV60517981; called by muse, mutect2, varscan2
- MICU3 | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100536655; called by muse, mutect2
- MLXIPL | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100515599; called by muse, mutect2, varscan2
- MRPS36 | c.125C>A p.S42* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99841129; called by muse, mutect2, varscan2
- MSANTD4 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100108682; called by muse, mutect2, varscan2
- MSH4 | c.1150G>C p.G384R | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV54195955, COSV99592761; called by muse, mutect2, varscan2
- MST1R | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV56574826; called by muse, mutect2, varscan2
- MTCL1 | c.4210G>A p.E1404K (on ENST00000306329 / NM_001378206.1; = p.E1085K on NM_015210.4) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV100093129, COSV60410727; called by muse, mutect2, varscan2
- MTHFD1 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99387456; called by muse, mutect2, varscan2
- MTMR11 | c.1016C>T p.S339L (on ENST00000439741 / NM_001145862.2; = p.S267L on NM_181873.3) | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54965741; called by muse, mutect2, varscan2
- MUC16 | c.31213G>A p.V10405I | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs201549151; called by muse, mutect2, varscan2
- MUC3A | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); catalogued as COSV60222025; called by muse, mutect2, varscan2
- MYB | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100215249; called by muse, mutect2, varscan2
- MYBBP1A | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99627253; called by muse, mutect2, varscan2
- MYH9 | c.3341C>G p.S1114C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV53381454; called by muse, mutect2, varscan2
- NADSYN1 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs776483679, COSV100035148; called by muse, varscan2
- NAV1 | c.3992C>G p.S1331C | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99819871; called by muse, mutect2, varscan2
- NBAS | c.6640G>A p.E2214K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV99872014; called by muse, mutect2, varscan2
- NBAS | c.5606C>T p.S1869F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99872016; called by muse, varscan2
- NBAS | c.5600C>A p.P1867Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99872017; called by muse, varscan2
- NBAS | c.3132C>T p.L1044= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as rs1219303434, COSV99866348, COSV99872019; called by muse, mutect2
- NCAN | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53055038; called by muse, mutect2, varscan2
- NCAN | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV99388538; called by muse, mutect2, varscan2
- NCAN | c.3784G>T p.G1262C | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99388543; called by muse, mutect2, varscan2
- NCAN | c.3785G>T p.G1262V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99388549; called by muse, mutect2, varscan2
- NCOA6 | c.4613C>G p.S1538C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100750432; called by muse, mutect2, varscan2
- NCOA6 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100750433; called by muse, varscan2
- NCOR2 | c.4378G>A p.D1460N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1476285882, COSV100657986; called by muse, mutect2
- NDUFAB1 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99141595; called by muse, mutect2, varscan2
- NEUROD1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV99717082; called by muse, mutect2, varscan2
- NID1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99938462; called by muse, mutect2
- NINJ1 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100966632; called by muse, mutect2, varscan2
- NISCH | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1407976197, COSV100617723; called by muse, mutect2, varscan2
- NKAIN2 | c.474+2T>A p.X158_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100864434; called by muse, mutect2, varscan2
- NKX3-2 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV101220028; called by muse, mutect2, varscan2
- NOS1 | c.3479C>G p.S1160C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501561; called by muse, mutect2, varscan2
- NPAS3 | c.449T>A p.L150* (on ENST00000356141 / NM_001164749.2; = p.L118* on NM_022123.3) | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100390404; called by muse, mutect2, varscan2
- NPAS4 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100215330; called by muse, mutect2, varscan2
- NPHS1 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 32/183 reads (17%) | catalogued as COSV100800336, COSV62289891; called by muse, mutect2, varscan2
- NPR1 | c.1759-1G>C p.X587_splice | Splice Site (SNP) | VAF 34/171 reads (20%) | catalogued as COSV100902088, COSV64118151; called by muse, mutect2, varscan2
- NPR3 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99423991; called by muse, mutect2, varscan2
- NR1D1 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52846097; called by muse, mutect2, varscan2
- NRG3 | c.920T>A p.I307N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100932696; called by muse, mutect2, varscan2
- NRP2 | c.2758G>A p.V920I (on ENST00000360409 / NM_201266.2; = p.V915I on NM_003872.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100761397; called by muse, mutect2, varscan2
- NUMA1 | c.6190C>G p.L2064V | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52620496, COSV99475031; called by muse, mutect2, varscan2
- NUP153 | c.4235C>G p.S1412* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV50454688, COSV99468052; called by muse, mutect2, varscan2
- OBSCN | c.713C>G p.S238* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99485539; called by muse, mutect2, varscan2
- ODF2L | c.1522G>A p.D508N (on ENST00000317336; = p.D492N on NM_020729.3) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs1257666567, COSV99644787; called by muse, mutect2
- OOSP2 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99613675; called by muse, mutect2, varscan2
- OR10G3 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100336153; called by muse, mutect2, varscan2
- OR10G9 | c.614T>A p.V205E | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1393112887, COSV100901793; called by muse, mutect2, varscan2
- OR10X1 | c.263G>C p.C88S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100936722; called by muse, mutect2, varscan2
- OR11G2 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV100640075; called by muse, mutect2, varscan2
- OR2G2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201323751, COSV100190050; called by muse, mutect2
- OR2L8 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1181361557, COSV100594209, COSV100594353; called by muse, mutect2, varscan2
- OR2T33 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100531658; called by muse, varscan2
- OR2T33 | c.780del p.K261Nfs*23 | Frame Shift Del (DEL) | VAF 45/193 reads (23%) | catalogued as COSV58813635; called by pindel, varscan2
- OR2T34 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100170593; called by muse, mutect2
- OR4A5 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as rs776561828, COSV60521582; called by muse, mutect2
- OR51B2 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV60916736; called by muse, mutect2, varscan2
- OR56A3 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61569164, COSV61569281; called by muse, mutect2, varscan2
- OR5H15 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as COSV100736792; called by muse, mutect2
- OR5M1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.595); catalogued as rs753527882, COSV101591620; called by muse, mutect2, varscan2
- OR6C75 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV100595474; called by muse, mutect2, varscan2
- OR6V1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101389589; called by muse, mutect2, varscan2
- ORC4 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as COSV99932538; called by muse, mutect2
- OSTN | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429709555, COSV100174154, COSV59138875; called by muse, mutect2
- OTOGL | c.557C>T p.S186L (on ENST00000547103; = p.S177L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV101509533; called by muse, mutect2, varscan2
- PAM | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.287); catalogued as rs1374876111, COSV99173942; called by muse, mutect2, varscan2
- PCDH11Y | c.836C>A p.P279Q (on ENST00000400457 / NM_032973.2; = p.P268Q on NM_032971.3) | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99293049; called by muse, mutect2, varscan2
- PCDH12 | c.1886G>C p.G629A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890580995, COSV51520477, COSV99191719; called by muse, mutect2, varscan2
- PCDHGA6 | c.1628G>C p.S543T | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99548843; called by muse, mutect2, varscan2
- PCDHGA8 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99548845; called by muse, mutect2, varscan2
- PCDHGB6 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99543173, COSV99548846; called by muse, mutect2, varscan2
- PCSK1 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.779); catalogued as COSV100227116, COSV100227310; called by muse, mutect2
- PDE3A | c.2165T>G p.M722R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100762928; called by muse, mutect2, varscan2
- PDE6A | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99678798; called by muse, mutect2, varscan2
- PEG10 | c.491G>T p.R164L (on ENST00000482108 / NM_001040152.2; = p.R198L on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV101509994, COSV71788008; called by muse, mutect2, varscan2
- PELO | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99252333; called by muse, mutect2, varscan2
- PENK | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs370083183; called by muse, mutect2, varscan2
- PEX1 | c.3523C>G p.P1175A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99952460; called by muse, mutect2
- PGLYRP1 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV99151543; called by muse, mutect2, varscan2
- PIEZO2 | c.7514C>T p.S2505F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53288008, COSV99555682; called by muse, mutect2, varscan2
- PIGR | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100732671; called by muse, mutect2, varscan2
- PIK3C2B | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100915098; called by muse, varscan2
- PIWIL1 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as COSV99807019; called by muse, mutect2, varscan2
- PKM | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.698); catalogued as COSV100065323; called by muse, mutect2, varscan2
- PLCG2 | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100842707; called by muse, mutect2, varscan2
- PLCH1 | c.233C>T p.S78F (on ENST00000340059 / NM_001130960.2; = p.S90F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100398488; called by muse, mutect2, varscan2
- PLD3 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as rs1243244199, COSV100735299; called by muse, mutect2, varscan2
- PLEKHA6 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV99692923; called by muse, mutect2, varscan2
- PLEKHM1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV101378902; called by muse, mutect2, varscan2
- PNMT | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99510840; called by muse, mutect2
- PNPLA8 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1380720211, COSV99993870; called by muse, mutect2, varscan2
- PNRC1 | c.217C>G p.R73G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.338); catalogued as COSV100260066, COSV60139463; called by muse, mutect2, varscan2
- POGLUT2 | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99959183; called by muse, mutect2, varscan2
- POLR1B | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1553410592, COSV99638714; called by muse, mutect2, varscan2
- POLR2I | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.532); catalogued as COSV99387604; called by muse, mutect2, varscan2
- POLR2I | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99387605; called by muse, mutect2, varscan2
- POM121 | c.1142C>G p.S381* (on ENST00000434423; = p.S116* on NM_172020.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/132 reads (24%) | catalogued as COSV99989421; called by muse, mutect2, varscan2
- POSTN | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.977); catalogued as rs1451791803, COSV101123531; called by muse, mutect2, varscan2
- PPIL4 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99481977; called by muse, mutect2, varscan2
- PPIP5K2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384354; called by muse, mutect2, varscan2
- PPP1R15A | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as COSV99566303; called by muse, mutect2, varscan2
- PPP1R26 | c.2323A>T p.S775C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.416); catalogued as COSV100778174; called by muse, mutect2, varscan2
- PREPL | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1558482256, COSV99576550; called by muse, mutect2, varscan2
- PREX2 | c.4219C>G p.L1407V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs746957295, COSV55761761, COSV55769145, COSV99910499; called by muse, mutect2, varscan2
- PRIMPOL | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100153303; called by muse, mutect2
- PRKACB | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as rs757439493, COSV100854098, COSV100854165; called by muse, mutect2, varscan2
- PRR11 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV51874306, COSV99231902; called by muse, mutect2, varscan2
- PRR30 | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99574876; called by muse, mutect2, varscan2
- PRUNE1 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99640023; called by muse, mutect2, varscan2
- PSENEN | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as COSV99495500; called by muse, mutect2, varscan2
- PTPRO | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs724159880, COSV55504336, COSV55504926; called by muse, mutect2, varscan2
- PUS10 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369863; called by muse, mutect2, varscan2
- PYHIN1 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV100932431, COSV63721392; called by muse, mutect2, varscan2
- QRICH2 | c.2825C>T p.S942L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99429837; called by muse, mutect2, varscan2
- QRICH2 | c.2662C>G p.P888A | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV99429839; called by muse, mutect2, varscan2
- RABGGTB | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100175258, COSV60638760; called by muse, mutect2
- RAP2B | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as COSV100059188; called by muse, mutect2, varscan2
- RAPH1 | c.2015G>T p.R672L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as rs199919809, COSV55582236; called by muse, mutect2, varscan2
- RASA3 | c.1206+2T>C p.X402_splice | Splice Site (SNP) | VAF 42/131 reads (32%) | catalogued as COSV100481332; called by muse, mutect2, varscan2
- RASGRF2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV99430778; called by muse, mutect2, varscan2
- RBM47 | c.762G>C p.M254I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV99921893; called by muse, mutect2, varscan2
- REXO1 | c.2954C>T p.S985L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99402710; called by muse, mutect2
- RHCE | c.645C>G p.F215L | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV99604508; called by muse, mutect2, varscan2
- RIF1 | c.3394C>G p.P1132A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99691409; called by muse, mutect2, varscan2
- RIT1 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.268); catalogued as COSV100851217; called by muse, mutect2, varscan2
- RNASE10 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100116227; called by muse, mutect2, varscan2
- RND3 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV55724631, COSV99812244; called by muse, mutect2, varscan2
- RNF146 | c.238G>A p.E80K (on ENST00000368314 / NM_001242850.2; = p.E79K on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs1211788654, COSV100541856; called by muse, mutect2, varscan2
- RNF17 | c.3856C>T p.Q1286* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as COSV99694675; called by muse, mutect2, varscan2
- RNF44 | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV99221867; called by muse, mutect2
- ROCK1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as COSV101296649; called by muse, mutect2, varscan2
- RSBN1 | c.2291C>G p.S764* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV54730789, COSV54732015; called by muse, mutect2, varscan2
- RSRC2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV59204150; called by muse, mutect2, varscan2
- RTF1 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.8); catalogued as COSV101047989, COSV101048310, COSV67478648; called by muse, mutect2, varscan2
- RTP4 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52019068; called by muse, mutect2, varscan2
- RUSC2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63430425; called by muse, mutect2, varscan2
- RYR2 | c.9447G>A p.E3149= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100773224; called by muse, mutect2
- S1PR4 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV55739655, COSV99859497; called by muse, mutect2, varscan2
- SARDH | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100061353; called by muse, mutect2, varscan2
- SCLT1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV99828621; called by muse, mutect2, varscan2
- SCNN1G | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV55597839; called by muse, mutect2, varscan2
- SCUBE1 | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99298772; called by muse, mutect2, varscan2
- SDE2 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 42/176 reads (24%) | catalogued as rs1362134334, COSV99682879; called by muse, mutect2, varscan2
- SDE2 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99682881; called by muse, mutect2, varscan2
- SEC14L1 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.178); catalogued as COSV101171245; called by muse, mutect2, varscan2
- SEMA3A | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs894076128, COSV99548219; called by muse, mutect2, varscan2
- SESTD1 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100090983; called by muse, mutect2, varscan2
- SETDB2 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1030300903, COSV99321075; called by muse, mutect2, varscan2
- SETX | c.3656C>T p.S1219L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99811232; called by muse, mutect2, varscan2
- SEZ6 | c.1778G>A p.C593Y | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379165521, COSV100253648; called by muse, mutect2, varscan2
- SFSWAP | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99906492; called by muse, mutect2, varscan2
- SH2D4B | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV100214306; called by muse, mutect2, varscan2
- SHMT1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs981203004, COSV100363711; called by muse, varscan2
- SIPA1 | c.2739C>G p.I913M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100425975; called by muse, mutect2, varscan2
- SIPA1 | c.2936C>G p.S979C | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100425838; called by muse, mutect2, varscan2
- SIPA1L3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs995224347, COSV55916572; called by muse, mutect2
- SLC12A6 | c.690T>C p.C230= (on ENST00000354181 / NM_001365088.1; = p.C179= on NM_005135.2) | Splice Region (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99273602; called by muse, mutect2, varscan2
- SLC24A5 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV99048323; called by muse, mutect2, varscan2
- SLC25A22 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1461046318, COSV100204340; called by muse, mutect2, varscan2
- SLC26A3 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV100385264, COSV100385340; called by muse, mutect2, varscan2
- SLC3A1 | c.45G>C p.M15I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99577753; called by muse, mutect2, varscan2
- SLC4A1 | c.2523C>G p.I841M | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV99293755; called by muse, mutect2, varscan2
- SLC4A3 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1482549467, COSV99813368; called by muse, mutect2, varscan2
- SLC5A1 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99833842; called by muse, mutect2, varscan2
- SLC6A19 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100443837, COSV58669696; called by muse, mutect2, varscan2
- SLC9A5 | c.2164A>G p.I722V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV100237672; called by muse, varscan2
- SMAGP | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs769883835, COSV101199462; called by muse, mutect2, varscan2
- SMARCB1 | c.578C>G p.S193C (on ENST00000263121; = p.S239C on NM_003073.5) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99575847; called by muse, varscan2
- SMC1B | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV100663575; called by muse, mutect2
- SMG6 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs1450179399, COSV99558897; called by muse, mutect2, varscan2
- SMIM15 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100171318; called by muse, mutect2, varscan2
- SNAP91 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as rs778793061, COSV99536915; called by muse, mutect2, varscan2
- SOCS4 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV100216397; called by muse, mutect2, varscan2
- SPATA5 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99916587; called by muse, mutect2, varscan2
- SPATA7 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV99248500; called by muse, mutect2
- SPATA9 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99174199; called by muse, mutect2, varscan2
- SPHKAP | c.3889G>A p.G1297R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs943936527, COSV60881624; called by muse, mutect2, varscan2
- SPTLC2 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99378023; called by muse, mutect2, varscan2
- SQOR | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV99526235; called by muse, mutect2, varscan2
- SRSF2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV100333790, COSV100334351; called by muse, mutect2, varscan2
- ST7 | c.1686G>C p.K562N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); catalogued as COSV55389561, COSV99623185; called by muse, mutect2, varscan2
- STAG1 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774492433, COSV52610653; called by muse, mutect2, varscan2
- STAM2 | c.1386G>C p.M462I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV99813407; called by muse, mutect2, varscan2
- STARD13 | c.2341G>A p.E781K (on ENST00000336934 / NM_001243476.3; = p.E663K on NM_052851.3) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716482; called by muse, mutect2, varscan2
- STAT1 | c.1815G>C p.E605D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100738930; called by muse, varscan2
- STAT1 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100738931; called by muse, mutect2, varscan2
- STAT6 | c.1506C>G p.F502L | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100273588; called by muse, mutect2, varscan2
- STK36 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs144827149; called by muse, mutect2, varscan2
- STKLD1 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs372995558, COSV100912031; called by muse, mutect2, varscan2
- STON1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1194693518, COSV100562353; called by muse, mutect2, varscan2
- SULF2 | c.2204G>A p.W735* | Nonsense Mutation (SNP) | VAF 54/178 reads (30%) | catalogued as COSV100737499; called by muse, mutect2, varscan2
- SULT6B1 | c.550G>C p.D184H (on ENST00000535679 / NM_001367551.1; = p.D146H on NM_001032377.2) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53194034, COSV99573354; called by muse, mutect2
- SUOX | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1366698332, COSV99907244; called by muse, mutect2, varscan2
- SUPT20H | c.2017C>G p.Q673E (on ENST00000350612 / NM_001014286.3; = p.Q674E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs763693655, COSV99524120; called by muse, mutect2, varscan2
- SYNE1 | c.6185G>T p.R2062L (on ENST00000367255 / NM_182961.4; = p.R2069L on NM_033071.3) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs542032376, COSV54995263, COSV55079091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR8 | c.788T>A p.V263E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99257390; called by muse, mutect2, varscan2
- TAF1L | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV99645588; called by muse, mutect2, varscan2
- TAF4B | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99301156; called by muse, mutect2, varscan2
- TAS1R3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100229927; called by muse, mutect2, varscan2
- TBC1D20 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs997533200; called by muse, mutect2
- TBC1D32 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV99251564; called by muse, mutect2
- TBC1D32 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99251566; called by muse, mutect2, varscan2
- TBXAS1 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV99696190; called by muse, mutect2, varscan2
- TCF20 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100167057; called by muse, mutect2, varscan2
- TCHH | c.4442A>T p.Q1481L | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100915578; called by muse, mutect2, varscan2
- TENM2 | c.2353T>A p.C785S (on ENST00000518659 / NM_001122679.2; = p.C553S on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101319489; called by muse, mutect2, varscan2
- TENM3 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV101305544; called by muse, mutect2, varscan2
- TENM4 | c.8088G>C p.Q2696H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53635415; called by muse, mutect2
- TET2 | c.2257A>T p.K753* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99485270; called by muse, mutect2, varscan2
- TFB2M | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV100829935; called by muse, mutect2, varscan2
- THAP1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV99576829; called by muse, mutect2, varscan2
- THUMPD3 | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100560810; called by muse, mutect2, varscan2
- TLE4 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99513452; called by muse, mutect2, varscan2
- TMEM168 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100454840; called by muse, mutect2, varscan2
- TMPRSS11B | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100219555; called by muse, mutect2, varscan2
- TNIK | c.3586G>A p.D1196N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52679790; called by muse, mutect2, varscan2
- TNR | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99692035; called by muse, mutect2, varscan2
- TOPORS | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV100859588; called by muse, mutect2
- TOR1AIP1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); catalogued as rs548996424, COSV54871553; called by muse, mutect2
- TOR1AIP1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs747644318, COSV54871298, COSV99621730; called by muse, mutect2, varscan2
- TPR | c.6404C>T p.P2135L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100824285; called by muse, mutect2
- TPR | c.2293C>T p.Q765* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV100824286; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1082A>T p.N361I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV99163061; called by muse, mutect2, varscan2
- TRAPPC10 | c.615G>C p.M205I | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.141); catalogued as COSV99379294; called by muse, mutect2, varscan2
- TREML1 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV100914346; called by muse, mutect2, varscan2
- TRHDE | c.2414A>C p.Q805P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99672992; called by muse, mutect2
- TRHDE | c.2416G>T p.A806S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.046); catalogued as COSV53869126, COSV99672994; called by muse, mutect2
- TRIM15 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100938923; called by muse, mutect2, varscan2
- TRIM35 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV57754665; called by muse, mutect2, varscan2
- TRIML2 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100455859, COSV100456415, COSV58717183; called by muse, mutect2, varscan2
- TSC22D2 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV100721170, COSV100721301; called by muse, mutect2
- TSHZ3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV99553061; called by muse, mutect2, varscan2
- TTC21B | c.2662G>T p.A888S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as COSV99693044; called by muse, mutect2, varscan2
- TTC31 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as COSV99282424; called by muse, mutect2, varscan2
- TTC31 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs371407213; called by muse, varscan2
- TTC31 | c.1386G>C p.L462F | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99282427; called by muse, varscan2
- TTC4 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV100988480; called by muse, mutect2, varscan2
- TTLL12 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV99333838; called by muse, mutect2
- TTLL4 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs557920337, COSV99293825; called by muse, mutect2, varscan2
- TTN | c.96528G>C p.E32176D (on ENST00000591111; = p.E24752D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | PolyPhen benign (0); catalogued as COSV59931803, COSV60324863; called by muse, mutect2, varscan2
- TTN | c.61363G>A p.E20455K (on ENST00000591111; = p.E13031K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | PolyPhen possibly damaging (0.654); catalogued as COSV59887757; called by muse, mutect2, varscan2
- TUBG1 | c.534G>C p.M178I | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99258370, COSV99258995; called by muse, mutect2, varscan2
- UBE2H | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs778682033, COSV62920323; called by muse, mutect2, varscan2
- UBN1 | c.2822C>G p.S941C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52174067, COSV99278767; called by muse, mutect2
- UNC13B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV101037486; called by muse, mutect2, varscan2
- USH2A | c.9250G>A p.D3084N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100243799; called by muse, mutect2, varscan2
- USH2A | c.9034C>T p.H3012Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56394868; called by muse, mutect2, varscan2
- USH2A | c.7985G>A p.R2662K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs1342651521, COSV56455118; called by muse, mutect2, varscan2
- USH2A | c.2667G>C p.L889F | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56348251, COSV56382247; called by muse, mutect2, varscan2
- USHBP1 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99394605; called by muse, mutect2, varscan2
- USP37 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV51447539, COSV99294961; called by muse, mutect2, varscan2
- USP39 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV100084155; called by muse, varscan2
- VAC14 | c.2217G>C p.Q739H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99935188; called by muse, mutect2, varscan2
- VCPKMT | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); catalogued as COSV99366928; called by muse, mutect2
- VLDLR | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV101173250; called by muse, mutect2, varscan2
- VOPP1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV99567648; called by muse, mutect2, varscan2
- VPS16 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100988671; called by muse, mutect2, varscan2
- WDFY3 | c.2943G>C p.M981I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99886115; called by muse, mutect2, varscan2
- WDR17 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54575293, COSV54583940, COSV54586090; called by muse, mutect2
- WDR49 | c.549C>G p.I183M (on ENST00000308378 / NM_001366158.1; = p.I524M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100393262, COSV57708541; called by muse, mutect2, varscan2
- WHAMM | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750566602, COSV99725318; called by muse, mutect2, varscan2
- XRN2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101018717, COSV65871382; called by muse, mutect2, varscan2
- ZBP1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100473953, COSV100474086; called by muse, mutect2
- ZBTB40 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs372091157; called by muse, mutect2, varscan2
- ZC3H13 | c.4502C>G p.S1501C (on ENST00000242848 / NM_001330565.2; = p.S1502C on NM_015070.6) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99669068; called by muse, mutect2, varscan2
- ZC4H2 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100565089; called by muse, mutect2, varscan2
- ZCWPW2 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV101075413, COSV67499388; called by muse, mutect2, varscan2
- ZFC3H1 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101110729; called by muse, mutect2, varscan2
- ZFX | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58447370; called by muse, mutect2, varscan2
- ZGPAT | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs754670538, COSV100203325; called by muse, mutect2
- ZIC4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV101268195; called by muse, mutect2
- ZMYM4 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.324); catalogued as COSV100111261; called by muse, mutect2, varscan2
- ZNF135 | c.1235G>T p.C412F (on ENST00000313434 / NM_001289401.2; = p.C424F on NM_003436.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536982, COSV57886663; called by muse, mutect2, varscan2
- ZNF142 | c.1288G>A p.E430K (on ENST00000411696 / NM_001379660.1; = p.E230K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV101377015; called by muse, mutect2, varscan2
- ZNF221 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.167); catalogued as rs781600241, COSV52110059; called by muse, mutect2, varscan2
- ZNF296 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99674214; called by muse, mutect2, varscan2
- ZNF33A | c.1832A>G p.N611S (on ENST00000458705 / NM_006974.3; = p.N612S on NM_006954.2) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.092); catalogued as rs1302820893, COSV100276291; called by muse, mutect2, varscan2
- ZNF384 | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100159007; called by muse, mutect2
- ZNF491 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100022106; called by muse, mutect2, varscan2
- ZNF496 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99666324; called by muse, mutect2, varscan2
- ZNF517 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100743604; called by muse, mutect2, varscan2
- ZNF527 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs532320672, COSV100648792; called by muse, mutect2, varscan2
- ZNF536 | c.3485C>T p.S1162F | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV100836126; called by muse, mutect2, varscan2
- ZNF557 | c.1164G>A p.M388I (on ENST00000414706 / NM_001044388.2; = p.M395I on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99422835; called by muse, mutect2, varscan2
- ZNF560 | c.1594C>G p.R532G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV100039152; called by muse, mutect2, varscan2
- ZNF566 | c.635C>G p.S212* | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | catalogued as COSV101091648; called by muse, mutect2, varscan2
- ZNF573 | c.535C>G p.L179V (on ENST00000536220 / NM_001172692.1; = p.L121V on NM_152360.3) | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.02); catalogued as COSV100265888; called by muse, mutect2
- ZNF608 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs527721257, COSV100102581; called by muse, mutect2, varscan2
- ZNF682 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100653374, COSV62067977; called by muse, mutect2, varscan2
- ZNF7 | c.1923G>C p.K641N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296174; called by muse, mutect2, varscan2
- ZNF791 | c.959G>C p.R320T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100589173; called by muse, mutect2, varscan2
- ZNF846 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as COSV101194404; called by muse, mutect2, varscan2
- ZNF93 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV59373906, COSV59377149; called by muse, mutect2, varscan2
- ZSCAN22 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs756419271, COSV100308545; called by muse, mutect2, varscan2
- C1RL | c.274del p.Q92Rfs*46 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- CRHR2 | c.1157C>G p.P386R | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ELP3 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2
- FCGBP | c.5548G>C p.D1850H | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FMNL2 | c.2275C>G p.L759V | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.171); called by muse, mutect2
- HKDC1 | c.1008del p.R337Gfs*58 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel*, varscan2
- HMCN1 | c.9305_9306del p.E3102Vfs*9 | Frame Shift Del (DEL) | VAF 32/158 reads (20%) | called by pindel, varscan2
- LYST | c.2632del p.L878Sfs*21 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- MAGEC1 | c.2744dup p.L915Ffs*41 | Frame Shift Ins (INS) | VAF 65/149 reads (44%) | called by mutect2, pindel, varscan2
- MED13 | c.3785_3786del p.H1262Pfs*53 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by pindel, varscan2
- MINPP1 | c.1413del p.S472Vfs*6 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- RNGTT | c.950del p.N317Ifs*30 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- SEMA4G | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SMARCAD1 | c.1040dup p.N347Kfs*4 | Frame Shift Ins (INS) | VAF 11/24 reads (46%) | called by mutect2, varscan2
- SMC6 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- SPANXB1 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.893); called by muse, mutect2
- SYNRG | c.3824C>G p.S1275* | Nonsense Mutation (SNP) | VAF 62/244 reads (25%) | called by muse, mutect2, varscan2
- TACC2 | c.3124dup p.E1042Gfs*8 | Frame Shift Ins (INS) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- TAP1 | c.255del p.V86Yfs*37 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | called by mutect2, pindel, varscan2
- ZNF782 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCA13 | c.11016C>T p.F3672= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs752761141, COSV101447277; called by muse, mutect2, varscan2
- ABCA7 | c.1269G>A p.S423= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs1245436357, COSV99566788; called by muse, mutect2, varscan2
- ABCA7 | c.2733G>C p.L911= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99566825; called by muse, mutect2
- ABCC12 | c.3048C>G p.L1016= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100253391; called by muse, mutect2, varscan2
- ABCG4 | c.1017G>A p.K339= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV56645225; called by muse, mutect2, varscan2
- AC100868.1 | c.1579C>T p.L527= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV51852798; called by muse, mutect2, varscan2
- AC109583.1 | c.1026C>A p.I342= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100168003; called by muse, mutect2, varscan2
- ACSF3 | c.411C>G p.V137= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV100441653; called by muse, mutect2, varscan2
- ADAM11 | c.918G>A p.L306= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as COSV99567919; called by muse, mutect2, varscan2
- ADAMTS12 | c.2112G>C p.V704= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100710287, COSV100711764; called by muse, varscan2
- ADAMTS16 | c.2748C>T p.V916= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs762164586, COSV99943410; called by muse, mutect2, varscan2
- ADGRV1 | c.13647G>A p.E4549= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101316658; called by muse, mutect2, varscan2
- AFF3 | c.2649C>G p.L883= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100420303; called by muse, mutect2, varscan2
- AGTPBP1 | c.3680G>A p.*1227= (on ENST00000357081 / NM_001330701.2; = p.*1187= on NM_015239.2) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1431460975, COSV100430401; called by muse, mutect2, varscan2
- AMZ1 | c.936C>T p.I312= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs576714230, COSV100406645; called by muse, mutect2, varscan2
- ANKRD34B | c.477G>A p.G159= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100103676; called by muse, mutect2, varscan2
- ANXA9 | c.918G>C p.L306= | Silent (SNP) | VAF 7/174 reads (4%) | catalogued as COSV100385726; called by muse, mutect2
- APBA3 | c.1020C>T p.L340= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs763100988, COSV99516557; called by muse, mutect2, varscan2
- APLNR | c.369C>T p.L123= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs759519899, COSV99951405, COSV99951717; called by muse, mutect2, varscan2
- APOB | c.8520G>A p.G2840= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV51935925, COSV99268597; called by muse, mutect2
- ARF6 | c.288C>T p.I96= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100028510; called by muse, mutect2, varscan2
- ARHGEF26 | c.244C>T p.L82= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100726702; called by muse, mutect2
- ASXL3 | c.3660C>T p.T1220= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV52460807; called by muse, mutect2, varscan2
- ATAD2 | c.1423C>T p.L475= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1011715840, COSV99785460; called by muse, mutect2, varscan2
- ATP1A3 | c.1290C>T p.L430= (on ENST00000545399 / NM_001256214.2; = p.L417= on NM_152296.5) | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV100132613; called by muse, mutect2, varscan2
- ATXN1 | c.2124G>A p.L708= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs891796127, COSV99788148; called by muse, mutect2, varscan2
- AUNIP | c.891C>T p.V297= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as COSV65352650; called by muse, mutect2, varscan2
- BCAS3 | c.2670G>A p.L890= (on ENST00000390652 / NM_001353144.2; = p.L875= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/194 reads (26%) | catalogued as rs766667067, COSV101177364; called by muse, mutect2, varscan2
- BCOR | c.567G>A p.L189= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100654332, COSV60698985; called by muse, mutect2, varscan2
- C2orf50 | c.459G>A p.K153= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV101059484; called by muse, mutect2
- C6orf118 | c.969G>A p.Q323= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs752649183, COSV100025285; called by muse, mutect2, varscan2
- CACNA2D1 | c.1155C>T p.F385= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs868483699, COSV100667577; called by muse, mutect2, varscan2
- CADM3 | c.549C>G p.P183= (on ENST00000368125 / NM_001127173.3; = p.P217= on NM_021189.5) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100930431; called by muse, mutect2, varscan2
- CADM3 | c.1158G>T p.G386= (on ENST00000368125 / NM_001127173.3; = p.G420= on NM_021189.5) | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV100929695; called by muse, mutect2, varscan2
- CCAR2 | c.1494A>T p.P498= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV99374397; called by muse, mutect2, varscan2
- CCDC134 | c.282C>T p.P94= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV55389136; called by muse, mutect2, varscan2
- CCDC61 | c.33C>T p.Y11= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs753831019, COSV54427641; called by muse, mutect2, varscan2
- CDO1 | c.285G>A p.L95= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV51664509, COSV99164844; called by muse, mutect2, varscan2
- CHGB | c.1791G>C p.L597= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100973149; called by muse, mutect2
- CHPF2 | c.2127C>T p.L709= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99223401; called by muse, mutect2, varscan2
- CIITA | c.2490C>T p.P830= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as rs909171126, COSV100162701; called by muse, mutect2, varscan2
- CLDN18 | c.570G>A p.V190= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99481059; called by muse, mutect2
- CNFN | c.336G>A p.E112= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV99706240; called by muse, mutect2, varscan2
- CNTNAP2 | c.144C>T p.F48= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100673731, COSV62267733; called by muse, mutect2, varscan2
- CNTNAP2 | c.1635G>A p.A545= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs755959345, COSV62180843, COSV62199646; called by muse, mutect2, varscan2
- COASY | c.1065C>T p.P355= | Silent (SNP) | VAF 66/249 reads (27%) | catalogued as COSV99888178; called by muse, mutect2, varscan2
- CPNE8 | c.639C>T p.F213= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100505216; called by muse, mutect2, varscan2
- CRNKL1 | c.336G>T p.A112= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV55636261, COSV99846278, COSV99846944; called by muse, mutect2, varscan2
- CTU2 | c.1497G>A p.E499= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99966696; called by muse, mutect2, varscan2
- DAB2IP | c.225C>T p.V75= (on ENST00000408936; = p.V47= on NM_032552.3) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99406526; called by muse, mutect2, varscan2
- DDX50 | c.1656G>A p.L552= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs116570019, COSV101007328; called by muse, mutect2, varscan2
- DMKN | c.1110C>T p.F370= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs151091067, COSV60091062; called by muse, mutect2, varscan2
- DRD4 | c.699C>T p.R233= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99448963; called by muse, mutect2, varscan2
- DSEL | c.165G>A p.Q55= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100026183; called by muse, mutect2, varscan2
- DSG2 | c.1443C>T p.I481= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99853640; called by muse, mutect2, varscan2
- DYNC2H1 | c.8304C>T p.F2768= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100519977; called by muse, mutect2, varscan2
- DYSF | c.3150C>T p.L1050= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV50337813; called by muse, mutect2, varscan2
- ENC1 | c.721C>T p.L241= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs529251638, COSV100187954, COSV56629619; called by muse, mutect2
- ENTPD8 | c.1230C>A p.L410= (on ENST00000371506 / NM_001033113.2; = p.L373= on NM_198585.3) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100395491; called by muse, mutect2, varscan2
- EPHX3 | c.495G>A p.S165= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs777666287, COSV55655950; called by muse, mutect2, varscan2
- ESF1 | c.2253T>C p.D751= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99176572; called by muse, mutect2, varscan2
- EXOSC5 | c.291G>A p.L97= | Silent (SNP) | VAF 32/274 reads (12%) | catalogued as rs759499806, COSV55371065; called by muse, mutect2, varscan2
- F10 | c.1107G>A p.E369= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as CM154325, COSV100979376; called by muse, mutect2, varscan2
- F12 | c.795C>T p.F265= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99499976; called by muse, mutect2, varscan2
- FAM71C | c.418C>T p.L140= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100175855; called by muse, mutect2, varscan2
- FAM81A | c.990A>T p.T330= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99893705; called by muse, mutect2, varscan2
- FBXO46 | c.1572C>G p.L524= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs755084145, COSV100480481; called by muse, varscan2
- FBXO46 | c.1509C>T p.F503= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV58348558; called by muse, varscan2
- FERMT1 | c.1908G>C p.L636= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV54093932, COSV99452251; called by muse, mutect2, varscan2
- FFAR1 | c.577C>T p.L193= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99323868; called by muse, mutect2, varscan2
- FHOD3 | c.186G>A p.Q62= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99943432; called by muse, mutect2, varscan2
- FILIP1L | c.1197C>A p.L399= (on ENST00000354552 / NM_182909.3; = p.L159= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV100497433; called by muse, mutect2, varscan2
- FLNC | c.5355C>T p.F1785= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as COSV100368935; called by muse, mutect2, varscan2
- FLNC | c.5901G>A p.L1967= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100368937; called by muse, mutect2, varscan2
- FLT3 | c.1728A>G p.L576= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99610453; called by muse, mutect2, varscan2
- FN1 | c.4167G>A p.R1389= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100118501; called by muse, mutect2, varscan2
- FYB1 | c.1056C>T p.T352= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100686564, COSV60941109; called by muse, mutect2, varscan2
- FZD2 | c.192G>A p.T64= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100190881; called by muse, mutect2, varscan2
- FZD4 | c.1581G>A p.V527= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs566786953, COSV101536082; called by muse, mutect2, varscan2
- GNRHR | c.390C>T p.F130= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56932884; called by muse, mutect2, varscan2
- GPR101 | c.78C>T p.I26= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV99981725; called by muse, varscan2
- GRID1 | c.1767G>A p.V589= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs767837102, COSV100027009; called by muse, mutect2, varscan2
- GUCY2C | c.1599G>A p.L533= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99664253; called by muse, mutect2, varscan2
- HIP1R | c.1572G>A p.K524= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99459405; called by muse, mutect2
- HMCN1 | c.9435C>T p.L3145= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV54898309; called by muse, mutect2, varscan2
- HTR2A | c.240G>A p.L80= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs768379574, COSV101096904; called by muse, mutect2, varscan2
- ICAM2 | c.483C>T p.F161= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as rs917341998, COSV99857060; called by muse, mutect2, varscan2
- IFT122 | c.2655C>T p.F885= (on ENST00000348417 / NM_052989.3; = p.F826= on NM_018262.4) | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV99959990; called by muse, mutect2, varscan2
- IGF1R | c.2808G>A p.L936= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV51281403; called by muse, mutect2
- IGFLR1 | c.138C>T p.F46= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV99495485; called by muse, mutect2
- IGSF9 | c.1797C>G p.V599= (on ENST00000368094 / NM_001135050.2; = p.V583= on NM_020789.4) | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100829670; called by muse, mutect2, varscan2
- IL10RA | c.90G>A p.P30= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs747872407, COSV57139746; ClinVar: likely benign; called by muse, mutect2, varscan2
- IMPG2 | c.594C>T p.L198= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1446868298, COSV99516672; called by muse, mutect2, varscan2
- ITGA11 | c.1897C>T p.L633= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100242325, COSV59879971; called by muse, mutect2, varscan2
- KIF16B | c.2775G>A p.Q925= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100735001; called by muse, mutect2
- KIF5A | c.2106G>A p.Q702= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99673683; called by muse, mutect2, varscan2
- KIRREL2 | c.1011G>A p.G337= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1203476912, COSV99384547; called by muse, mutect2, varscan2
- KLHDC7A | c.1425G>C p.L475= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV68768989, COSV68771386; called by muse, mutect2, varscan2
- KLHL32 | c.105G>A p.Q35= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100987479, COSV100987522; called by muse, mutect2, varscan2
- LATS1 | c.1608C>T p.T536= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs750014191, COSV99486883; called by muse, mutect2, varscan2
- LRRC45 | c.2012G>A p.*671= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100141988; called by muse, mutect2
- MAGEC1 | c.393T>A p.P131= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV99596758; called by muse, mutect2, varscan2
- MANEA | c.1176A>T p.T392= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100721698; called by muse, mutect2, varscan2
- MBTPS1 | c.2916G>A p.V972= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100597876; called by muse, mutect2, varscan2
- MELTF | c.972C>G p.L324= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as COSV56383673, COSV99586683; called by muse, mutect2
- MIGA1 | c.396A>G p.R132= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100889823; called by muse, mutect2, varscan2
- MKI67 | c.7239G>C p.L2413= | Silent (SNP) | VAF 6/129 reads (5%) | catalogued as COSV100897065; called by muse, mutect2
- MLLT6 | c.774G>T p.S258= | Silent (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- MMP19 | c.387G>C p.L129= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV100491296; called by muse, mutect2, varscan2
- MPEG1 | c.1059C>T p.L353= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV57097340; called by muse, mutect2
- MRPL9 | c.288C>G p.L96= | Silent (SNP) | VAF 8/241 reads (3%) | called by muse, mutect2
- MTG2 | c.1155G>A p.L385= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1440398158, COSV63693331; called by muse, mutect2, varscan2
- MUC16 | c.21711G>A p.Q7237= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV101202072, COSV67453552; called by muse, mutect2, varscan2
- MUC3A | c.777C>T p.I259= | Silent (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- MVK | c.153C>T p.L51= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1207622143, COSV57169933, COSV99904694; called by muse, mutect2, varscan2
- MYCBPAP | c.2175G>A p.V725= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV100089282; called by muse, mutect2, varscan2
- MYH4 | c.1032C>T p.F344= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99700395, COSV99700414; called by muse, mutect2, varscan2
- NACC2 | c.174G>T p.L58= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- NBAS | c.1977C>T p.L659= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99868701, COSV99872022; called by muse, mutect2
- NCF4 | c.693T>A p.P231= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV99957589; called by muse, mutect2, varscan2
- NCKAP5L | c.3846G>A p.T1282= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs757061176, COSV100259332; called by muse, varscan2
- NDUFB5 | c.42G>A p.A14= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1422766692, COSV52021290, COSV99372696; called by muse, mutect2, varscan2
- NFXL1 | c.831C>T p.P277= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100217113; called by muse, mutect2, varscan2
- NMT2 | c.1068C>T p.N356= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100975674; called by muse, mutect2, varscan2
- NOBOX | c.918C>T p.A306= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99779780; called by muse, mutect2, varscan2
122 further variants in this file (0 protein-altering or splice-affecting, 96 silent, 26 other) are not listed here.
